Somatic mutation profile of tumor specimen TARGET-10-PARCKD-09A (aliquot TARGET-10-PARCKD-09A-01D) from TARGET case TARGET-10-PARCKD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (928 days).
Specimen TARGET-10-PARCKD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92def1d2-4eb9-4544-9ad3-507146aca124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCKD-10A (Blood Derived Normal), aliquot TARGET-10-PARCKD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e52cbc3-288d-496d-95ed-ee185f685eb0

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 3, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIK3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776869541, COSV100902536; called by muse, mutect2, varscan2
- IL7 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1012908736; called by muse, mutect2, varscan2
- JAK1 | c.2108G>T p.S703I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61087718, COSV61088652; called by muse, mutect2, varscan2
- TNXB | c.11110G>A p.V3704M (on ENST00000647633; = p.V3457M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199623625; called by muse, mutect2, varscan2
- ACOT6 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESCO1 | c.1363A>C p.M455L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAJ48 | chr14:22490478 del TTAGAACACTGTGTATCTAACTTTGGA | Missense Mutation (DEL) | VAF 30/113 reads (27%) | called by mutect2, varscan2
- CSMD3 | c.8355C>T p.C2785= (on ENST00000297405 / NM_001363185.1; = p.C2616= on NM_052900.3) | Silent (SNP) | VAF 61/168 reads (36%) | catalogued as rs1258675208, COSV99836967; called by muse, mutect2, varscan2
- TPI1 | c.330G>T p.G110= (on ENST00000229270; = p.G73= on NM_000365.6) | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- LINC01257 | n.418C>T | RNA (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2, varscan2
- PRKACA | c.420-27G>A | Intron (SNP) | VAF 29/63 reads (46%) | catalogued as rs375422928; called by muse, mutect2, varscan2
- RPL27A | c.143+288T>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- SEC14L4 | c.911+41G>A | Intron (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
